Somatic mutation profile of tumor specimen CUPP-B49F-TTM1-A (aliquot CUPP-B49F-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B49F, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 76.1 years (27,793 days).
Specimen CUPP-B49F-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0113fb13-8f7f-4f77-89d0-323880212936.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B49F-NT1-A (FFPE Scrolls), aliquot CUPP-B49F-NT1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd95f8ad-a39f-418a-81e4-a941399e8d42

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, varscan2
- NETO1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- PTPN12 | c.1330C>G p.Q444E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
